Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1ZZ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1ZZ-06A (Metastatic).

Prof.Dr.

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, NOS C77.9
for 7/24/11

Patient: Xxxx
geb. *** **

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixated specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 95 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 1 mitoses per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a sheet like growth pattern. Lymphocytic infiltrates compound approx. 5 percent of the tissue cells.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr.

CWCF Site = lymph node

Primary Tumor Site Discrepancy not stated on path		☒

Source: NCI Genomic Data Commons file cfce93bc-7f01-4efe-9e0e-be9ce33c8ff0 (TCGA-FS-A1ZZ.E65D23A7-1FD6-4672-9B26-5B087AE90370.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).